Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A9TH, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A9TH-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE:

RECEIVED DATE:

REPORT DATE:

COPY TO: [REDACTED]

ICD O-3

Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9

Q4 5/5/14

Pre-Op Diagnosis

Prostate cancer

Post-Op Diagnosis

Nothing indicated

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled [REDACTED] - prostate, left and right pelvic lymph nodes, portion of vas deferens" is a previously sectioned, markedly distorted prostate gland with attached fragments of apparent seminal vesicles. The specimen is received after tissue harvest for [REDACTED]. Within the specimen container are three tissue cassettes labeled [REDACTED]. The prostate fragments with apparent attached seminal vesicles weigh as received 52.5 grams and measure on reconstruction approximately 5.4 x 4.6 x 4.5 cm. The outer surface is markedly shaggy. The cut surface shows markedly gritty gray tan fibrotic cut surface with focal punctate areas of chalky discoloration extending throughout the entire distal and mid region of the specimen focally into the proximal area (near the vesical) margin. The urethra appears to be compressed. This tissue occupies a total area of approximately 4.5 x 4.0 x 4.0 cm and grossly appears to extend to the apical (distal) margin and to several inked lateral margins. The lesion grossly extends to the seminal vesicles which appear to be grossly fragmented. The portions of the seminal vesicles together are 2.5 x 2.0 x 0.9 cm with lobulated gray tan outer surfaces and multicystic gray tan fibrotic cut surfaces. Also received in the same container are three elongated fragments of soft gray tan tissue which appear to be tubular with pinpoint lumen. They measure from 2.0 x 0.4 x 0.4 cm to 3.0 x 0.4 x 0.4 cm. Discrete gross lesions are not identified. Also received in the same container are 5.6 x 5.5 x 1.5 cm tan yellow fibroadipose tissue fragments which on palpation and

[page 2 of 3]
sectioning reveal two poorly defined tan yellow to brown nodules 3.8 and 4.4 cm. Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle; S - representative tubular tissue fragments; T-U - entire smaller nodule; V-W - entire larger nodule.

Microscopic Description:

Reviewed are slides labeled [REDACTED]

Final Diagnosis

Prostate, radical prostatectomy with bilateral pelvic lymph nodes and portion of vas deferens (resection):

Prostate size:

Weight: 52.5 grams.

Size: 5.4 x 4.6 x 4.5 cm.

Lymph node sampling: Bilateral pelvic lymph nodes.

Histologic type: Adenocarcinoma.

Histologic pattern:

Primary pattern: Grade 5

Secondary pattern: Grade 4

Tertiary pattern: Grade 5

Total Gleason score: 9

Tumor quantitation:

Proportion of prostate involved by tumor: Approximately 90%.

Extraprostatic extension: See comment.

Seminal vesicle invasion: Present, bilateral.

Surgical margins: Adenocarcinoma extends to the apical, bladder neck and multiple soft tissue margins.

Lymphovascular invasion: Not identified.

Perineural invasion: Present, extensive.

Pathologic stage: pT3b N0

Number of lymph nodes examined: Two (right and left pelvic nodes).

Number of lymph nodes containing metastatic carcinoma: Zero (0/2).

Other:

Portion of vas deferens demonstrating involvement by carcinoma.

PAS 9 SPC-A

CPT: 88309, 88305 x 3

Comments

Histologic sections demonstrate extensive involvement by high grade prostatic adenocarcinoma. Much of the prostate is replaced by tumor. Prominent areas of cribriforming are noted; multiple areas of single cells infiltrating through the stroma are also present. Extensive involvement of the seminal vesicles (both right and left) is seen; tumor extension to multiple soft tissue margins of resection, including along perineural tracts, is seen. Involvement of both the apical as well as bladder neck margins is seen. Clinical correlation

[page 3 of 3]
and correlation with intraoperative findings is recommended.

At the request of the undersigned pathologist for quality assurance purposes, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file 09c7573f-6552-492c-a4f2-6cbb58ff4090 (TCGA-HC-A9TH.C2755FC2-E4BD-4997-B2F9-1F1C3A9C28AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).